Somatic mutation profile of tumor specimen 0DKFA7 from CCDI case PBBXMR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 11.2 years (4,104 days).
Specimen 0DKFA7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38ae11da-916b-4d50-8667-f9f2a0e9f9a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKF9M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6565859a-1599-4901-8b45-fb013c1174af

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, 3'UTR 3, 5'UTR 2, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 94/528 reads (18%) | catalogued as rs377767326, CM064283, COSV61684940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 102/609 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 80/637 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- C12orf40 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 75/508 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs757398186, COSV61132520; called by muse, mutect2, varscan2
- DCAF12L1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 118/375 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV64421672; called by muse, mutect2, varscan2
- GALNT3 | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 133/815 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV67062662; called by muse, mutect2, varscan2
- MGA | c.8581C>T p.R2861W (on ENST00000219905 / NM_001164273.1; = p.R2652W on NM_001080541.2) | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs749267770, COSV54948011; called by muse, mutect2, varscan2
- MUC16 | c.27254C>A p.S9085Y | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV67458266; called by muse, mutect2, varscan2
- RPTOR | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 89/510 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs995035426, COSV60813647; called by muse, mutect2, varscan2
- TCERG1 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 45/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1047211226, COSV99695102; called by muse, mutect2
- TTN | c.30440G>A p.R10147Q (on ENST00000591111; = p.R9220Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/986 reads (6%) | PolyPhen probably damaging (0.986); catalogued as rs727504757, COSV100611691; ClinVar: uncertain significance; called by muse, mutect2
- CRAT | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 54/515 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DCAF8L1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DENND6A | c.1621-2A>T p.X541_splice | Splice Site (SNP) | VAF 131/803 reads (16%) | called by muse, mutect2, varscan2
- EIF3H | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 129/655 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM171B | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 93/945 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- KLHL1 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 48/720 reads (7%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); called by muse, mutect2
- MIA3 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 158/1173 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NFU1 | c.496G>A p.D166N (on ENST00000410022 / NM_001002755.4; = p.D142N on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/449 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- PAN2 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 58/840 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); called by muse, mutect2
- POC5 | c.1531G>A p.V511I (on ENST00000428202 / NM_001099271.2; = p.V486I on NM_152408.2) | Missense Mutation (SNP) | VAF 82/1075 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIRT6 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 96/481 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRRAP | c.9952C>A p.L3318M (on ENST00000359863 / NM_001244580.1; = p.L3289M on NM_003496.3) | Missense Mutation (SNP) | VAF 87/840 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TULP2 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 64/856 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TXNRD3 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBE3A | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 80/1051 reads (8%) | called by muse, mutect2
- UHMK1 | c.443T>G p.F148C | Missense Mutation (SNP) | VAF 102/679 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS13D | c.4787A>T p.H1596L | Missense Mutation (SNP) | VAF 135/671 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DLGAP4 | c.108C>T p.P36= | Silent (SNP) | VAF 70/581 reads (12%) | catalogued as rs771034907; called by muse, mutect2, varscan2
- FMN1 | c.3516G>A p.L1172= (on ENST00000616417 / NM_001277313.2; = p.L949= on NM_001103184.4) | Silent (SNP) | VAF 90/629 reads (14%) | called by muse, mutect2, varscan2
- RAB44 | c.1143G>A p.P381= | Silent (SNP) | VAF 42/229 reads (18%) | catalogued as rs554291431; called by muse, varscan2
- RBM28 | c.2070G>A p.K690= | Silent (SNP) | VAF 150/759 reads (20%) | called by muse, mutect2, varscan2
- RPUSD4 | c.720G>A p.A240= | Silent (SNP) | VAF 138/708 reads (19%) | catalogued as rs758635318; called by muse, mutect2, varscan2
- ADAM2 | c.-35G>T | 5'UTR (SNP) | VAF 58/290 reads (20%) | catalogued as rs1412612551; called by muse, mutect2, varscan2
- AP5Z1 | c.1806-23C>T | Intron (SNP) | VAF 14/76 reads (18%) | catalogued as rs1197844023; called by mutect2, varscan2
- GRHPR | c.*35C>T | 3'UTR (SNP) | VAF 100/517 reads (19%) | catalogued as rs1289071698, COSV57038730; called by muse, mutect2, varscan2
- JPT2 | c.*21G>A | 3'UTR (SNP) | VAF 64/289 reads (22%) | catalogued as rs745415228; called by muse, mutect2, varscan2
- NPLOC4 | c.-18G>C | 5'UTR (SNP) | VAF 60/390 reads (15%) | called by muse, mutect2, varscan2
- OR2G6 | c.*53C>T | 3'UTR (SNP) | VAF 32/158 reads (20%) | called by muse, mutect2, varscan2
